Somatic mutation profile of tumor specimen TCGA-BP-5008-01A (aliquot TCGA-BP-5008-01A-01D-1462-08) from TCGA case TCGA-BP-5008, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 46.6 years (17,008 days).
Specimen TCGA-BP-5008-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3f3f897-9ea6-4706-8bf4-1a9e3a6193f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5008-11A (Solid Tissue Normal), aliquot TCGA-BP-5008-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c377f54d-ff76-4962-8a45-5ae5c833dfe3

The open-access MAF lists 41 somatic variants for this specimen: 34 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 27, Silent 7, Frame Shift Del 4, Splice Site 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.4684C>A p.L1562I | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as COSV66063660; called by muse, mutect2, varscan2
- ABHD17A | c.155C>A p.P52H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV51749156; called by mutect2, varscan2
- ACSM3 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.708); catalogued as COSV55499722; called by muse, mutect2, varscan2
- ADAMTS2 | c.1579A>C p.K527Q | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51071979; called by muse, mutect2, varscan2
- BTAF1 | c.101A>T p.K34M | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56429764; called by muse, mutect2, varscan2
- BTBD11 | c.1343G>A p.G448D | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV55016715; called by muse, mutect2
- CLCN5 | c.310A>G p.N104D | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV56582259; called by muse, mutect2, varscan2
- DBI | c.191-2A>T p.X64_splice (on ENST00000355857 / NM_001079862.3; = p.X81_splice on NM_020548.8 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 31/169 reads (18%) | catalogued as COSV61055271, COSV61055492; called by muse, mutect2, varscan2
- DIAPH3 | c.849T>A p.N283K (on ENST00000400324 / NM_001042517.2; = p.N20K on NM_030932.3) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV57364806; called by muse, mutect2, varscan2
- DNAH7 | c.1916T>G p.L639R | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56751383; called by muse, mutect2, varscan2
- FAT4 | c.12039G>C p.L4013F | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58671144; called by muse, mutect2, varscan2
- FAT4 | c.12040C>A p.L4014I | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.979); catalogued as COSV58671164; called by muse, mutect2, varscan2
- HAGH | c.712A>G p.N238D | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1223813636, COSV68400139; called by muse, mutect2, varscan2
- HECW1 | c.517A>T p.T173S | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67821483; called by muse, mutect2, varscan2
- IFNA5 | c.385G>C p.V129L | Missense Mutation (SNP) | VAF 51/294 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs370988896, COSV52386209; called by muse, mutect2, varscan2
- KLHL24 | c.1409A>T p.D470V | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV54424542; called by muse, mutect2
- LOXL4 | c.1443G>C p.W481C | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53254971; called by muse, mutect2, varscan2
- MYG1 | c.1019G>A p.C340Y | Missense Mutation (SNP) | VAF 54/245 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV52932179; called by muse, mutect2, varscan2
- MYG1 | c.1020C>A p.C340* | Nonsense Mutation (SNP) | VAF 56/245 reads (23%) | catalogued as COSV52932185, COSV52934508; called by muse, mutect2, varscan2
- MYO9A | c.3417G>C p.R1139S | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as COSV61847488; called by muse, mutect2
- PLEKHG1 | c.2891T>C p.L964P | Missense Mutation (SNP) | VAF 69/318 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV62044964; called by muse, mutect2, varscan2
- PLEKHH2 | c.634A>C p.M212L | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV56749537; called by muse, mutect2, varscan2
- RALGAPA1 | c.3752T>C p.L1251P | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV51876323, COSV51890559; called by muse, mutect2, varscan2
- RASSF6 | c.275T>G p.L92R (on ENST00000342081 / NM_201431.2; = p.L60R on NM_177532.5) | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV56716334, COSV56720184; called by muse, mutect2, varscan2
- RPL30 | c.232A>G p.N78D | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as COSV54635547; called by muse, mutect2, varscan2
- RWDD3 | c.519G>T p.M173I | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.365); catalogued as COSV55721321; called by muse, mutect2
- SLC29A3 | c.470C>G p.T157S | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.254); catalogued as COSV64384459; called by muse, mutect2, varscan2
- SLCO1B1 | c.1061G>A p.G354D | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs769283535, COSV57007047, COSV99919199; called by muse, mutect2, varscan2
- ZBED9 | c.1547A>T p.Q516L | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.546); catalogued as COSV71729151; called by muse, mutect2
- CDKL1 | c.729_734del p.D243_P244del | In Frame Del (DEL) | VAF 40/300 reads (13%) | called by mutect2, pindel, varscan2
- CELSR1 | c.3032del p.N1011Tfs*72 | Frame Shift Del (DEL) | VAF 25/128 reads (20%) | called by mutect2, pindel, varscan2
- FBXO48 | c.252_255del p.A85Cfs*6 | Frame Shift Del (DEL) | VAF 24/283 reads (8%) | called by mutect2, pindel
- TEKT5 | c.1077_1084del p.L360Dfs*111 | Frame Shift Del (DEL) | VAF 22/163 reads (13%) | called by mutect2, pindel, varscan2
- VPS13A | c.6916_6917del p.T2306* | Frame Shift Del (DEL) | VAF 23/166 reads (14%) | called by mutect2, pindel, varscan2
- CRYBG2 | c.3756C>T p.L1252= | Silent (SNP) | VAF 37/147 reads (25%) | catalogued as COSV57483628; called by muse, mutect2, varscan2
- CS | c.777C>T p.L259= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs146737473, COSV60833832; called by muse, mutect2, varscan2
- DHX35 | c.870T>A p.V290= | Silent (SNP) | VAF 39/201 reads (19%) | catalogued as COSV52667311; called by muse, mutect2, varscan2
- FBXO38 | c.291A>G p.L97= | Silent (SNP) | VAF 41/244 reads (17%) | catalogued as rs1339219934, COSV57025717; ClinVar: likely benign; called by muse, mutect2, varscan2
- POTEH | c.567C>A p.V189= | Silent (SNP) | VAF 18/183 reads (10%) | catalogued as COSV100624809, COSV100624830; called by muse, mutect2, varscan2
- ROCK2 | c.1203A>G p.K401= | Silent (SNP) | VAF 54/231 reads (23%) | catalogued as COSV55075667; called by muse, mutect2, varscan2
- ZNF862 | c.330C>A p.A110= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV56222666; called by mutect2, varscan2
